Somatic mutation profile of tumor specimen HCM-BROD-0199-C71-02A (aliquot HCM-BROD-0199-C71-02A-11D-A80U-36) from HCMI case HCM-BROD-0199-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.1 years (17,924 days).
Specimen HCM-BROD-0199-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cb1f1b8-bf22-48b3-9163-58be82f5ca67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0199-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0199-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd0d6c9d-ebc8-47da-8f7d-8a1510764d39

The open-access MAF lists 73 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 19, Frame Shift Del 6, Nonsense Mutation 4, 3'UTR 3, 5'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 170/416 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD163L1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs139153315; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 200/456 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CEL | c.2101T>G p.S701A (on ENST00000673714; = p.S698A on NM_001807.6) | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs587780310; ClinVar: uncertain significance; called by muse, varscan2
- CTAGE6 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1186223985; called by mutect2, varscan2
- DNAI1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs752354598, COSV54280364, COSV54280621; called by muse, mutect2, varscan2
- DROSHA | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 135/335 reads (40%) | catalogued as COSV60781622; called by muse, mutect2, varscan2
- ESPNL | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 227/544 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs778024556, COSV54541083; called by muse, mutect2, varscan2
- GRB7 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 173/227 reads (76%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.532); catalogued as rs201668668; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 132/291 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2, varscan2
- GUCY1B1 | c.1823dup p.N608Kfs*11 | Frame Shift Ins (INS) | VAF 58/155 reads (37%) | catalogued as rs757993339; called by mutect2, pindel, varscan2
- HMCN1 | c.10904G>A p.R3635Q | Missense Mutation (SNP) | VAF 168/401 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs777872545, COSV54908505; called by muse, mutect2, varscan2
- LETM1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 209/437 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201510306, COSV57103367; called by muse, mutect2, varscan2
- NLRP3 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 177/383 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs199637520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRROS | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 265/607 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs986757744; called by muse, mutect2, varscan2
- PPP3R2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 214/546 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1200972717, COSV62455332; called by muse, mutect2, varscan2
- PTEN | c.183T>G p.H61Q | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64289119, COSV99057944; called by muse, mutect2, varscan2
- REPS2 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 194/212 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58184927; called by muse, mutect2, varscan2
- STIM2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52838637; called by muse, mutect2, varscan2
- TAFA3 | c.319del p.E107Rfs*41 | Frame Shift Del (DEL) | VAF 174/493 reads (35%) | catalogued as COSV62624991; called by mutect2, pindel, varscan2
- TSKS | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 211/489 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as rs1317673712; called by muse, mutect2, varscan2
- TTC28 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 156/420 reads (37%) | catalogued as COSV67414832; called by muse, mutect2, varscan2
- UBR4 | c.3617C>G p.S1206C | Missense Mutation (SNP) | VAF 173/439 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs555728639, COSV64382807; called by muse, mutect2, varscan2
- ZNF333 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 211/523 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1240772288; called by muse, mutect2, varscan2
- ZNF831 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 339/656 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64040754; called by muse, mutect2, varscan2
- AFF2 | c.3191C>G p.T1064S | Missense Mutation (SNP) | VAF 121/145 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ANKS1A | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 312/708 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD6 | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 159/359 reads (44%) | called by muse, mutect2, varscan2
- CPA6 | c.293T>G p.L98* | Nonsense Mutation (SNP) | VAF 151/292 reads (52%) | called by muse, mutect2, varscan2
- CYP21A2 | c.996C>A p.S332R | Missense Mutation (SNP) | VAF 294/806 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, varscan2
- DGKI | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 143/656 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DPP4 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPHA8 | c.2252T>A p.L751H | Missense Mutation (SNP) | VAF 251/575 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO45 | c.283del p.D95Tfs*76 | Frame Shift Del (DEL) | VAF 172/516 reads (33%) | called by mutect2, pindel, varscan2
- FNIP2 | c.2193T>G p.F731L | Missense Mutation (SNP) | VAF 160/363 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRM6 | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 342/831 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MTUS2 | c.2544_2546delinsG p.L849Gfs*39 | Frame Shift Del (DEL) | VAF 232/601 reads (39%) | called by pindel, varscan2*
- PAQR3 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 59/151 reads (39%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4714A>G p.T1572A | Missense Mutation (SNP) | VAF 235/1054 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- RFT1 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 208/507 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTBDN | c.543C>G p.C181W (on ENST00000393233 / NM_001270444.1; = p.C213W on NM_031429.2) | Missense Mutation (SNP) | VAF 275/696 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SSC4D | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 276/1214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VPS13D | c.12159C>A p.F4053L | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZAP70 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 279/609 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZFYVE26 | c.3928T>C p.S1310P | Missense Mutation (SNP) | VAF 35/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF462 | c.6174_6175del p.C2059Lfs*7 | Frame Shift Del (DEL) | VAF 173/519 reads (33%) | called by pindel, varscan2
- ZNF629 | c.2168_2169del p.F723Wfs*5 | Frame Shift Del (DEL) | VAF 183/554 reads (33%) | called by mutect2, pindel, varscan2
- ZNF708 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZSCAN29 | c.7del p.A3Pfs*5 | Frame Shift Del (DEL) | VAF 101/313 reads (32%) | called by mutect2, pindel, varscan2
- CILP | c.1767G>A p.L589= | Silent (SNP) | VAF 264/627 reads (42%) | catalogued as COSV99973097; called by muse, mutect2, varscan2
- CLEC4M | c.627G>C p.T209= | Silent (SNP) | VAF 68/475 reads (14%) | catalogued as rs59003279; called by muse, varscan2
- FLNC | c.5433G>A p.R1811= | Silent (SNP) | VAF 228/1001 reads (23%) | called by muse, mutect2, varscan2
- IGF1 | c.108G>A p.A36= | Silent (SNP) | VAF 207/474 reads (44%) | catalogued as rs371125874; called by muse, mutect2, varscan2
- MAP3K20 | c.1908G>A p.S636= | Silent (SNP) | VAF 154/370 reads (42%) | catalogued as rs112889653; called by mutect2, varscan2
- MUC12 | c.13509G>A p.P4503= (on ENST00000379442; = p.P4360= on NM_001164462.1) | Silent (SNP) | VAF 97/1857 reads (5%) | catalogued as rs775731625; called by muse, mutect2
- NCAM2 | c.1134T>C p.Y378= | Silent (SNP) | VAF 122/307 reads (40%) | called by muse, mutect2, varscan2
- OBSCN | c.21444G>A p.A7148= | Silent (SNP) | VAF 335/416 reads (81%) | catalogued as rs375088814; called by muse, mutect2, varscan2
- PIK3C2G | c.2868C>T p.N956= (on ENST00000676171; = p.N915= on NM_004570.5) | Silent (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- RNF151 | c.360G>A p.S120= | Silent (SNP) | VAF 310/725 reads (43%) | catalogued as rs374940392, COSV58400005; called by muse, mutect2, varscan2
- RRP1 | c.807C>T p.P269= | Silent (SNP) | VAF 101/244 reads (41%) | catalogued as rs774930391, COSV101513845, COSV101513866; called by muse, mutect2, varscan2
- SCUBE2 | c.855G>A p.T285= | Silent (SNP) | VAF 127/292 reads (43%) | catalogued as rs553227629; called by muse, mutect2, varscan2
- SEMA3C | c.720G>T p.V240= | Silent (SNP) | VAF 78/368 reads (21%) | called by muse, mutect2, varscan2
- SOCS4 | c.225G>A p.E75= | Silent (SNP) | VAF 125/319 reads (39%) | called by muse, mutect2, varscan2
- SPOCD1 | c.867C>T p.P289= | Silent (SNP) | VAF 232/495 reads (47%) | catalogued as rs370591004, COSV57100233; called by muse, mutect2, varscan2
- TAF3 | c.2118G>A p.K706= | Silent (SNP) | VAF 95/137 reads (69%) | called by muse, mutect2, varscan2
- TGM7 | c.732C>T p.G244= | Silent (SNP) | VAF 226/587 reads (39%) | catalogued as rs765744133; called by muse, mutect2, varscan2
- TM6SF2 | c.600C>T p.T200= | Silent (SNP) | VAF 128/311 reads (41%) | catalogued as rs748636134; called by muse, mutect2, varscan2
- ZSWIM4 | c.231G>A p.R77= | Silent (SNP) | VAF 231/504 reads (46%) | catalogued as rs1203070982, COSV99584488; called by muse, mutect2, varscan2
- CPLX2 | c.*134G>C | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- KCNJ1 | c.*47_*53del | 3'UTR (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- SIX4 | c.-148C>A | 5'UTR (SNP) | VAF 10/19 reads (53%) | catalogued as rs759558105; called by muse, mutect2, varscan2
- TMEM37 | c.-46G>A | 5'UTR (SNP) | VAF 152/364 reads (42%) | called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 48/210 reads (23%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
